Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1J8, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1J8-01A (Primary Tumor).

1CD-0-3

Carcinoma, infiltrating ductal, nos 8500/3
S. to breast, nos 850.9 3/11/11

page 1 / 1

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination (cito)

Examination No.:

Patient: PESEL: Age Gender: F

Material: Multiple organ resection - right breast
Unit in charge

Physician in charge:

Material collected on: Material received on:

Expected time of examination: 5 working days

Clinical diagnosis:

Examination performed on

Macroscopic description:

Right breast, sized 21.3 x 18.6 x 4.8 cm, removed along with axillary tissues sized 10 x 7 x 3.5 cm and a skin flap of 19.2 x 7.1 cm. Weight 923 g.

Tumour sized 3.3 x 1.8 x 3.2 cm on the border of outer quadrants, placed 2.2 cm from the lower edge, 0.3 cm from the base and 2.8 cm from the skin. Lymph nodes of 0.4 cm in length, fat.

Microscopic description:

Carcinoma ductale invasivum - NHG2 (3 + 3 + 2:14 mitoses/10 HPF, visual area diameter 0.55 mm). Mamilla sine laesionibus.

Glandular tissue showing mastopathia fibrosa et cystica. (fibrocystic changes)

AXILLARY LYMPH NODES

Metastases carcinomatosae in lymphonodis (No III/XVI).

Examination result/Histopathology diagnosis:

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the right breast

Metastases carcinomatosae in lymphonodis axillae (NO III/XVI). Cancer metastases in axillary lymph nodes (No III/XVI) (NHG2, pT2, pN1a).

Compliance validated by:

Examination performed on

Results of immunohistochemical examination:

Estrogen receptors found in 75% of neoplastic cell nuclei. Progesterone receptors found in 10-75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 0)

Compliance validated by:

Source: NCI Genomic Data Commons file 778af309-7109-474b-a34e-ced8d332a928 (TCGA-D8-A1J8.E8E799F8-158D-4AEC-8F86-D40F132C071C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).